Somatic mutation profile of tumor specimen MP2PRT-PAVHCS-TMP1-A (aliquot MP2PRT-PAVHCS-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVHCS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.2 years (2,262 days).
Specimen MP2PRT-PAVHCS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0043060-0002-46dc-8f1a-39299e881b31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHCS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHCS-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae05fae8-1203-4110-b411-2ebda9bbcb9a

The open-access MAF lists 24 somatic variants for this specimen: 15 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, Intron 3, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP5F1C | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 54/755 reads (7%) | catalogued as rs1415391887; called by muse, mutect2
- CACNG5 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 38/714 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs376464596; called by muse, mutect2
- FBN2 | c.2486C>T p.T829M | Missense Mutation (SNP) | VAF 105/331 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs575873653, COSV52491086; called by muse, mutect2, varscan2
- MOB3C | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 251/523 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs1312840476, COSV54718909; called by muse, mutect2, varscan2
- TBX18 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 55/551 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs987207695, COSV63736139, COSV63737235; called by muse, mutect2, varscan2
- TEX30 | c.248A>G p.N83S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs1166971329, COSV65696519; called by muse, mutect2, varscan2
- WWC1 | c.2147G>A p.R716Q | Missense Mutation (SNP) | VAF 77/521 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs577644875; called by muse, mutect2, varscan2
- ZSCAN1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 274/598 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as rs145743431, COSV56603241; called by muse, mutect2, varscan2
- CLEC12B | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 62/241 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EML6 | c.1935T>G p.V645= | Splice Region (SNP) | VAF 76/248 reads (31%) | called by muse, mutect2
- LANCL1 | c.920A>G p.D307G | Missense Mutation (SNP) | VAF 75/487 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- MAGEL2 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 224/486 reads (46%) | SIFT deleterious, low confidence (0); called by muse, varscan2
- MRPS30 | c.324C>A p.Y108* | Nonsense Mutation (SNP) | VAF 251/797 reads (31%) | called by muse, mutect2, varscan2
- NAP1L2 | c.758C>A p.T253K | Missense Mutation (SNP) | VAF 103/391 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.062); called by muse, varscan2
- PCDH10 | c.933G>C p.E311D | Missense Mutation (SNP) | VAF 247/822 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CTNND2 | c.30G>C p.A10= | Silent (SNP) | VAF 33/800 reads (4%) | called by muse, mutect2
- HMCN1 | c.8928C>T p.V2976= | Silent (SNP) | VAF 95/370 reads (26%) | catalogued as rs1324915270, COSV54940556; called by muse, mutect2, varscan2
- MTSS1 | c.1023G>A p.E341= | Silent (SNP) | VAF 49/303 reads (16%) | called by muse, mutect2, varscan2
- OR1S1 | c.165C>T p.N55= | Silent (SNP) | VAF 133/305 reads (44%) | catalogued as rs199668390, COSV58705936; called by muse, mutect2, varscan2
- PNLIPRP1 | c.105C>T p.G35= | Silent (SNP) | VAF 38/988 reads (4%) | catalogued as rs781876317, COSV62613567; called by muse, mutect2
- TCF24 | c.465A>G p.K155= | Silent (SNP) | VAF 80/217 reads (37%) | called by muse, mutect2, varscan2
- ASPSCR1 | c.1354-1341G>A | Intron (SNP) | VAF 129/654 reads (20%) | called by muse, mutect2, varscan2
- CADPS2 | c.3312+727A>C | Intron (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- GRIA2 | c.2406+463G>C | Intron (SNP) | VAF 53/250 reads (21%) | called by muse, mutect2, varscan2
